TARGET case TARGET-20-PAUMCH — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3a4475e6-5ab8-4a50-a247-f0a687807da7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 9 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 9.5 years (3,463 days); Year of diagnosis: 2011; Days to last follow up: 3,174 days (8.7 years).
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML0631.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (1 entry)
- Days to follow up: 3,174 days (8.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,174; Year of follow up: 2020.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 5.5 ×10³/µL; Blast Count 47%; Bone Marrow blast count 85%.

Biospecimens (1 sample)
- Sample TARGET-20-PAUMCH-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AAML1031_AAML0631_additionalCasesForSortedCellsAndCBExperiment_20230720.xlsx:
- First Event: Censored
- Overall Survival Time in Days: 3174
- WBC at Diagnosis: 5.5
- Bone marrow leukemic blast percentage (%): 85
- Peripheral blasts (%): 47
- FAB Category: M3
- Cytogenetic Complexity: 4
- Primary Cytogenetic Code: PML-RARA
- ISCN: 46,XY,del(7)(q11.2q22),t(11;16)(q25;q13),t(15;17)(q24;q21)[10]/46,XY,del(7)(q11.2q22),t(15;17)(q24;q21),der(16)(t(11;16)[3]/46,XY,der(1),add(1)(p36)add(1)(q32),del(7)(q11.2q22),t(11;16)(q25;q13),t(15;17)(q24;q21)[3]/46,XY[4]
- SCT in 1st CR: No
